TARGET case TARGET-10-PALJCF — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/06a7148f-9c3c-51d2-82d1-9ba30801beaa

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 3.5 years (1,275 days); Year of diagnosis: 2002; Days to last follow up: 4,671 days (12.8 years).
   Treatment given: Protocol identifier: P9906.

Follow-up (1 entry)
- Days to follow up: 4,671 days (12.8 years); Event-free: no event (relapse, second malignancy or death) recorded through day 4,671; Year of follow up: 2014.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 214 ×10³/µL.
- Day 8: Bone Marrow blast count 27%; Minimal Residual Disease (Flow Cytometry) 4.53%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (10 samples)
- Sample TARGET-10-PALJCF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-10-PALJCF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PALJCF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PALJCF-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
- Samples TARGET-10-PALJCF-60.1A, TARGET-10-PALJCF-60.1B, TARGET-10-PALJCF-60.2A, TARGET-10-PALJCF-60.3A, TARGET-10-PALJCF-60.4A, TARGET-10-PALJCF-60.5A (6 with the same recorded description): Sample type: Primary Xenograft Tissue; Tissue type: Tumor; Tumor descriptor: Xenograft.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 4671
- WBC at Diagnosis: 214
- CNS Status at Diagnosis: CNS 3
- MRD Day 8: 4.53
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.1
- Bone Marrow Site of Relapse: No
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 27
- BMA Blasts Day 29: 0
- Karyotype: 51,XX,+X,+8,+8,+14,+21[14]/46,XX[6]
- Down Syndrome: No
- DNA Index: 1.1
- Cell of Origin: B precursor (Non-T, Non-B ALL)
- ALL Molecular Subtype: Hyperdiploidy without trisomy of both chromsomes 4 and 10

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_I_20230727.xlsx:
- ALL Molecular Subtype: Hyperdiploidy without trisomy of both chromosomes 4 and 10

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Xenografts_20230727.xlsx:
- Event Free Survival Time in Days: 4672
- Protocol: 9906
- Cell of Origin: B Cell ALL
